Somatic mutation profile of tumor specimen TCGA-G9-7522-01A (aliquot TCGA-G9-7522-01A-11D-2260-08) from TCGA case TCGA-G9-7522, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.4 years (18,033 days).
Specimen TCGA-G9-7522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1247b364-6012-4a00-ae96-8824758b2b83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-7522-10A (Blood Derived Normal), aliquot TCGA-G9-7522-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45acf741-489e-4712-8099-c8820e86bba7

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK5RAP1 | c.1222C>T p.R408C (on ENST00000357886 / NM_001365728.1; = p.R394C on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/544 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as rs759307435, COSV59425658, COSV59426869; called by muse, mutect2, varscan2
- KCNU1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs369264156; called by muse, mutect2, varscan2
- PPP1R3B | c.514T>G p.Y172D | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV60098829; called by muse, mutect2, varscan2
- PTPRC | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); catalogued as rs375051221, COSV61405641; called by muse, mutect2
- RFX6 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as rs766695745, COSV60583298; called by muse, mutect2, varscan2
- SCN4A | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV71125418; called by muse, mutect2, varscan2
- SUN2 | c.1746G>A p.W582* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as rs1370457089, COSV53301333; called by mutect2, varscan2
- VILL | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs372162890; called by muse, mutect2, varscan2
- AHNAK | c.2308del p.D770Mfs*2 | Frame Shift Del (DEL) | VAF 36/345 reads (10%) | called by mutect2, pindel, varscan2
- DNAJB8 | c.168G>C p.L56= | Silent (SNP) | VAF 29/300 reads (10%) | catalogued as COSV59877933; called by muse, mutect2
